Somatic mutation profile of tumor specimen 0D9W5T from CCDI case PBBHZD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 4.9 years (1,785 days).
Specimen 0D9W5T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c5f39cd-5f56-4e8c-9960-17e6aaf592fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9W5U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be017ac9-fd1e-409d-ae9e-4944b3321152

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, 5'UTR 1, 5'Flank 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMBN | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 178/495 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs144905737, COSV59825844; called by muse, mutect2, varscan2
- B4GALNT2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 180/494 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs776879040, COSV55928297; called by muse, mutect2, varscan2
- CNPY2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 192/465 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs777195609; called by muse, mutect2, varscan2
- FBN2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 173/482 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs528614556, COSV52495649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD5 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 149/429 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV68724657; called by muse, mutect2, varscan2
- HEPH | c.1294C>T p.R432* (on ENST00000343002; = p.R165* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 162/404 reads (40%) | catalogued as COSV57961523, COSV57962751; called by muse, mutect2, varscan2
- KRTAP9-1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 211/517 reads (41%) | SIFT tolerated (0.24); catalogued as rs761048984; called by muse, mutect2, varscan2
- NFATC1 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 156/349 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778343943; called by muse, mutect2, varscan2
- NRP1 | c.2238G>T p.E746D | Missense Mutation (SNP) | VAF 203/455 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV55161947; called by muse, mutect2, varscan2
- WDR64 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.301); catalogued as rs1302850245, COSV63793738, COSV63796103; called by muse, mutect2, varscan2
- ATR | c.7726C>G p.P2576A | Missense Mutation (SNP) | VAF 226/583 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCN5 | c.2109C>A p.F703L | Missense Mutation (SNP) | VAF 184/463 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KLHL33 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.239); called by muse, mutect2
- MYOF | c.4852C>A p.L1618M | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OVCH1 | c.282-2A>G p.X94_splice | Splice Site (SNP) | VAF 79/241 reads (33%) | called by muse, mutect2, varscan2
- PTGER2 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 125/299 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SART1 | c.1813G>A p.G605S | Missense Mutation (SNP) | VAF 125/512 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SIRT3 | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 119/550 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SZT2 | c.4214T>C p.V1405A (on ENST00000634258 / NM_001365999.1; = p.V1348A on NM_015284.4) | Missense Mutation (SNP) | VAF 233/576 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TMC4 | c.299G>A p.R100K (on ENST00000617472 / NM_001145303.3; = p.R94K on NM_144686.4) | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated (0.99); PolyPhen benign (0.254); called by muse, mutect2
- ZNF385D | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 157/430 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP40 | c.114G>A p.Q38= | Silent (SNP) | VAF 261/689 reads (38%) | called by muse, mutect2, varscan2
- C9orf116 | c.381C>T p.Y127= | Silent (SNP) | VAF 185/473 reads (39%) | called by muse, mutect2, varscan2
- DOCK2 | c.2118G>A p.A706= | Silent (SNP) | VAF 189/509 reads (37%) | catalogued as rs569671710; called by muse, mutect2, varscan2
- KNDC1 | c.3681C>T p.D1227= | Silent (SNP) | VAF 40/538 reads (7%) | catalogued as rs771151872; called by muse, mutect2
- RAD51AP2 | c.1539T>A p.I513= | Silent (SNP) | VAF 85/188 reads (45%) | catalogued as COSV67587998; called by muse, mutect2, varscan2
- ZMIZ1 | c.1032C>A p.G344= | Silent (SNP) | VAF 17/405 reads (4%) | catalogued as COSV100566631, COSV57891659; called by muse, mutect2
- MRPS35 | chr12:27710800 C>T | 5'Flank (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- SLC22A15 | c.-52G>A | 5'UTR (SNP) | VAF 109/248 reads (44%) | catalogued as COSV101047142; called by muse, mutect2, varscan2
